Somatic mutation profile of tumor specimen MP2PRT-PARLPN-TMP1-A (aliquot MP2PRT-PARLPN-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PARLPN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.7 years (2,463 days).
Specimen MP2PRT-PARLPN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a50a23c-1bd4-4440-9ab8-d25e964a88ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARLPN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARLPN-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ee8ff2b-9204-4c75-8293-df6bb05ae34e

The open-access MAF lists 84 somatic variants for this specimen: 65 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 18, Nonsense Mutation 10, Splice Region 1, Intron 1, Frame Shift Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1603C>T p.Q535* | Nonsense Mutation (SNP) | VAF 14/414 reads (3%) | catalogued as rs1567843917, CM1512913, COSV62199278; ClinVar: pathogenic; called by muse, mutect2
- ADGRB3 | c.2213G>C p.R738T | Missense Mutation (SNP) | VAF 25/411 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV65391708; called by muse, mutect2
- ADGRV1 | c.13279G>A p.G4427R | Missense Mutation (SNP) | VAF 96/272 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV67984378; called by muse, varscan2
- AK4 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 102/311 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV59199840; called by muse, mutect2, varscan2
- BRCA2 | c.6851C>G p.S2284* | Nonsense Mutation (SNP) | VAF 48/155 reads (31%) | catalogued as COSV66450211; called by muse, mutect2, varscan2
- CHRNB1 | c.1360G>C p.D454H | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV60141964; called by muse, mutect2, varscan2
- DICER1 | c.3302C>G p.S1101C | Missense Mutation (SNP) | VAF 21/347 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs779748717; ClinVar: uncertain significance; called by muse, mutect2
- EIF2AK2 | c.1475C>G p.S492* | Nonsense Mutation (SNP) | VAF 82/202 reads (41%) | catalogued as COSV99240374; called by muse, varscan2
- ELOA2 | c.496G>A p.G166S | Missense Mutation (SNP) | VAF 291/654 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.739); catalogued as rs939991772; called by muse, mutect2, varscan2
- ERICH1 | c.601G>C p.G201R | Missense Mutation (SNP) | VAF 52/722 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.241); catalogued as COSV50640633; called by muse, mutect2
- EXPH5 | c.3434C>T p.S1145L | Missense Mutation (SNP) | VAF 172/445 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.315); catalogued as COSV56207429; called by muse, mutect2, varscan2
- FAT1 | c.12808C>T p.R4270* | Nonsense Mutation (SNP) | VAF 260/518 reads (50%) | catalogued as rs373689624, CM157665; called by muse, mutect2, varscan2
- FBXO38 | c.3209G>A p.R1070Q (on ENST00000340253 / NM_205836.3; = p.R995Q on NM_030793.5) | Missense Mutation (SNP) | VAF 132/272 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs761433013, COSV57025550; called by muse, mutect2, varscan2
- FOXP2 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 88/244 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63494146; called by muse, mutect2, varscan2
- KHDRBS2 | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 222/476 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.868); catalogued as rs760579776, COSV55423132; called by muse, mutect2, varscan2
- KTN1 | c.2980C>G p.H994D | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.076); catalogued as rs1436018799; called by muse, mutect2, varscan2
- LMNTD1 | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 118/269 reads (44%) | catalogued as COSV51450288; called by muse, mutect2, varscan2
- LRP1 | c.11334C>T p.I3778= | Splice Region (SNP) | VAF 206/408 reads (50%) | catalogued as rs138595744; called by muse, mutect2, varscan2
- LRP2 | c.8440G>A p.E2814K | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55545475; called by muse, mutect2
- OR2T4 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 308/614 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as rs370187385, COSV63543913; called by muse, varscan2
- PLA2R1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 112/240 reads (47%) | SIFT tolerated (0.87); PolyPhen benign (0.396); catalogued as rs867927849; called by muse, mutect2, varscan2
- PTRH2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 170/628 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs1371576060; called by muse, mutect2, varscan2
- SLC19A1 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 316/679 reads (47%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.488); catalogued as COSV100229328, COSV100229370; called by muse, varscan2
- SLC22A15 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 20/494 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1003764093; called by muse, mutect2
- TP53 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 20/310 reads (6%) | catalogued as CM044725, COSV52746809, COSV52814837, COSV53366474; called by muse, mutect2
- TRPV5 | c.1144G>C p.D382H | Missense Mutation (SNP) | VAF 216/457 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99520771; called by muse, mutect2, varscan2
- USP43 | c.2681C>T p.S894L | Missense Mutation (SNP) | VAF 44/299 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs756895822, COSV53300717; called by muse, mutect2, varscan2
- WTIP | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 249/537 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs1363566857; called by muse, mutect2, varscan2
- ZNF277 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 17/400 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV62462979; called by muse, mutect2
- ALPL | c.1066G>C p.D356H | Missense Mutation (SNP) | VAF 218/607 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARNT2 | c.1627C>T p.H543Y | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0.424); called by muse, mutect2
- ATP10B | c.1290C>G p.I430M | Missense Mutation (SNP) | VAF 188/516 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- CD83 | c.88G>C p.D30H | Missense Mutation (SNP) | VAF 124/361 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CDK5RAP2 | c.4301C>G p.S1434C | Missense Mutation (SNP) | VAF 113/213 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CHD4 | c.3400G>A p.D1134N (on ENST00000357008 / NM_001363606.2; = p.D1147N on NM_001273.5) | Missense Mutation (SNP) | VAF 92/248 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- CHD4 | c.3208G>C p.E1070Q (on ENST00000357008 / NM_001363606.2; = p.E1083Q on NM_001273.5) | Missense Mutation (SNP) | VAF 118/284 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CTCF | c.419del p.N140Mfs*14 | Frame Shift Del (DEL) | VAF 193/466 reads (41%) | called by mutect2, pindel, varscan2
- CYP7B1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DDX46 | c.2179C>G p.Q727E | Missense Mutation (SNP) | VAF 150/316 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- DICER1 | c.4409C>T p.S1470F | Missense Mutation (SNP) | VAF 42/532 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); called by muse, mutect2
- FRAS1 | c.1079C>G p.S360* | Nonsense Mutation (SNP) | VAF 16/282 reads (6%) | called by muse, mutect2
- GABRB1 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 131/307 reads (43%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- GDA | c.116G>T p.S39I | Missense Mutation (SNP) | VAF 191/386 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GDI2 | c.1280C>G p.S427* | Nonsense Mutation (SNP) | VAF 130/390 reads (33%) | called by muse, mutect2
- GFRA1 | c.818C>G p.S273C | Missense Mutation (SNP) | VAF 161/394 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GNL3L | c.133C>A p.H45N | Missense Mutation (SNP) | VAF 33/280 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1109 | c.43C>G p.Q15E | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2
- LMNTD1 | c.645T>G p.H215Q | Missense Mutation (SNP) | VAF 115/266 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- LRIT3 | c.964G>C p.D322H | Missense Mutation (SNP) | VAF 140/394 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- NR3C2 | c.2425C>G p.L809V | Missense Mutation (SNP) | VAF 104/324 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PCM1 | c.4642G>T p.E1548* | Nonsense Mutation (SNP) | VAF 30/468 reads (6%) | called by muse, mutect2
- PGM3 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 103/276 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PNPLA6 | c.3019G>A p.V1007M (on ENST00000414982 / NM_001166111.2; = p.V959M on NM_006702.5) | Missense Mutation (SNP) | VAF 226/463 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- RASGRF2 | c.1547T>C p.L516P | Missense Mutation (SNP) | VAF 90/170 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- RNF152 | c.244C>G p.P82A | Missense Mutation (SNP) | VAF 166/487 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.111); called by muse, mutect2
- SCP2 | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 129/278 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- SEC16B | c.3049C>T p.L1017F | Missense Mutation (SNP) | VAF 163/347 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- SERINC2 | c.1039G>C p.V347L (on ENST00000373709 / NM_178865.5; = p.V351L on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 197/438 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SI | c.3407G>C p.R1136T | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNRNP70 | c.666-11_678del p.X222_splice | Splice Site (DEL) | VAF 138/411 reads (34%) | called by pindel, varscan2
- SPATA2 | c.140C>G p.S47* | Nonsense Mutation (SNP) | VAF 246/536 reads (46%) | called by muse, mutect2, varscan2
- TRARG1 | c.333dup p.C112Lfs*75 | Frame Shift Ins (INS) | VAF 40/362 reads (11%) | called by mutect2, pindel, varscan2
- ZDBF2 | c.6992C>T p.S2331L | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- ZNF140 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 27/503 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- ZNF790 | c.1594G>C p.E532Q | Missense Mutation (SNP) | VAF 126/354 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- AATK | c.3807G>T p.G1269= (on ENST00000326724 / NM_001080395.3; = p.G1166= on NM_004920.2) | Silent (SNP) | VAF 312/1050 reads (30%) | catalogued as COSV58370544; called by muse, mutect2
- C7orf61 | c.480G>A p.L160= | Silent (SNP) | VAF 243/599 reads (41%) | called by muse, mutect2, varscan2
- CCNO | c.1041G>A p.P347= | Silent (SNP) | VAF 99/339 reads (29%) | catalogued as COSV57005265; called by muse, mutect2, varscan2
- CDCA4 | c.687C>T p.G229= | Silent (SNP) | VAF 330/666 reads (50%) | catalogued as rs572420251, COSV60314926; called by muse, mutect2, varscan2
- CELF5 | c.1119G>A p.A373= | Silent (SNP) | VAF 64/748 reads (9%) | catalogued as rs369842870; called by muse, mutect2
- CELSR3 | c.4834C>A p.R1612= | Silent (SNP) | VAF 212/402 reads (53%) | catalogued as COSV50851657; called by muse, varscan2
- CHD4 | c.2322C>A p.I774= (on ENST00000357008 / NM_001363606.2; = p.I787= on NM_001273.5) | Silent (SNP) | VAF 199/462 reads (43%) | catalogued as COSV100538000; called by muse, mutect2, varscan2
- EXOC4 | c.867G>A p.L289= | Silent (SNP) | VAF 15/492 reads (3%) | called by muse, mutect2
- GRM8 | c.2271C>T p.I757= | Silent (SNP) | VAF 207/450 reads (46%) | catalogued as COSV58806096, COSV58820351; called by muse, mutect2, varscan2
- PITX2 | c.60G>A p.A20= | Silent (SNP) | VAF 113/261 reads (43%) | called by muse, mutect2, varscan2
- PPP1R9A | c.1731C>G p.L577= | Silent (SNP) | VAF 12/378 reads (3%) | called by muse, mutect2
- PRKDC | c.4257G>A p.L1419= | Silent (SNP) | VAF 155/321 reads (48%) | called by muse, mutect2, varscan2
- RNF31 | c.3027C>G p.L1009= | Silent (SNP) | VAF 18/475 reads (4%) | called by muse, mutect2
- RPP38 | c.216G>A p.L72= | Silent (SNP) | VAF 33/376 reads (9%) | called by muse, mutect2
- SATB2 | c.1035C>T p.I345= | Silent (SNP) | VAF 211/517 reads (41%) | catalogued as COSV53492167; called by muse, mutect2, varscan2
- SSTR5 | c.579C>T p.P193= | Silent (SNP) | VAF 78/862 reads (9%) | catalogued as rs368327024; called by muse, mutect2
- SUSD5 | c.1398G>A p.T466= | Silent (SNP) | VAF 178/387 reads (46%) | catalogued as rs763797995, COSV58877522; called by muse, mutect2, varscan2
- ZNF484 | c.126C>T p.F42= | Silent (SNP) | VAF 84/228 reads (37%) | called by muse, mutect2, varscan2
- GANC | c.201+2541C>G | Intron (SNP) | VAF 95/250 reads (38%) | called by muse, mutect2, varscan2
